Gene-level copy-number profile of tumor specimen HCM-CSHL-0075-C25-01B from HCMI case HCM-CSHL-0075-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 74.8 years (27,321 days).
Specimen HCM-CSHL-0075-C25-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b6abb97b-ae2b-4b4f-bcdd-b7689fce14b2.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0075-C25-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,232 have no estimate.
https://portal.gdc.cancer.gov/files/ed76224a-d4d2-47ea-855d-b56ddf37c809

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 80; copy number 1: 722; copy number 2: 3,653; copy number 3: 1,976; copy number 4: 23,156; copy number 5: 3,506; copy number 6: 14,691; copy number 7: 3,654; copy number 8: 5,499; copy number 9: 144; copy number 10: 161; copy number 11: 269; copy number 12: 634; copy number 13: 8; copy number 14: 77; copy number 16: 39; copy number 17: 10; copy number 19: 1; copy number 20: 31; copy number 23: 24; copy number 25: 11; copy number 27: 30; copy number 34: 10; copy number 45: 5.

Homozygous deletions (total copy number 0; autosomes only): 80 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:68,509,441–68,670,652, 6 genes (within-gene range 0–4): UGT2B29P, UGT2B17, AC147055.2, AC147055.4, AC147055.3, UGT2B15.
- chr9:21,160,235–26,805,862, 74 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,454 genes in 36 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,461,221–144,474,790, 41 genes, copy number 11: AC239859.4, NKAIN1P1, AC239859.2, LINC02799, AC239859.1, NBPF17P, PFN1P12, RNU1-114P, RNVU1-17, RNVU1-23, RNVU1-18, AC239800.2, AC239800.1, FAM91A3P, AC239800.3, LINC02591, RNU1-143P, AC239798.1, AC239798.2, FCGR1CP, H2BP2, H3-2, AC246680.1, RPL22P5, FAM72C, SRGAP2D, IGKV1OR1-1, AC244015.1, AC244015.2, LINC02802, RNA5SP529, DRD5P2, AC245595.1, PPIAL4E, AC246785.4, RNVU1-15, AC246785.3, AC246785.2, NBPF15, PFN1P6, AC246785.1.
- chr4:67,417,305–67,468,251, 4 genes, copy number 9: AC104806.2, RNU1-63P, RNA5SP527, AC104806.1.
- chr4:76,214,040–76,898,144, 19 genes, copy number 16: FAM47E, AC034139.1, FAM47E-STBD1, STBD1, CCDC158, SNX5P1, RNU6-1000P, AC096743.2, AC096743.1, SHROOM3, AC112249.1, RNU6-145P, MIR4450, MIR548AH, SHROOM3-AS1, AC107072.1, AC104687.2, AC104687.1, SOWAHB.
- chr4:79,587,302–80,204,329, 10 genes, copy number 17: OR7E94P, AC092542.1, LINC02469, PCAT4, SNORA75, ANTXR2, KPNA2P1, RPSAP39, AC021127.1, PRDM8.
- chr4:81,030,708–81,057,627, 1 gene, copy number 16: BMP3.
- chr4:120,639,090–120,922,870, 4 genes, copy number 16: AC025741.1, PRDM5, RNU6-550P, SETP12.
- chr4:173,924,207–173,991,024, 1 gene, copy number 9 (within-gene range 4–9): AC106895.2.
- chr5:17,625,551–17,670,571, 10 genes, copy number 14: H3P21, TAF11L13, TAF11L14, AC233724.4, AC233724.1, AC233724.5, AC233724.2, H3Y1, AC233724.8, H3P22.
- chr5:44,495,099–45,895,970, 12 genes, copy number 11: LINC02224, AC093292.1, RN7SL383P, MRPS30-DT, AC093297.1, MRPS30, AC093297.2, AC114954.1, HCN1, AC117529.2, AC117529.1, AC122694.1.
- chr7:3,301,252–4,269,000, 1 gene, copy number 9 (within-gene range 5–9): SDK1.
- chr7:4,130,181–5,781,696, 41 genes, copy number 9: AC017000.1, CYP3A54P, FOXK1, AC092428.1, AP5Z1, MIR4656, AC092610.1, RADIL, Y_RNA, PAPOLB, RPL22P16, MMD2, RNF216P1, AC092032.2, RBAK-RBAKDN, AC092032.3, AC092032.1, SPDYE19P, RBAK, RBAKDN, OR10AH1P, ZNF890P, RNU6-215P, WIPI2, SLC29A4, TNRC18, AC093620.1, AC092171.1, AC092171.4, AC092171.3, AC092171.5, FBXL18, AC092171.2, MIR589, ACTB, AC006483.2, AC006483.1, FSCN1, RNF216, RNF216-IT1, MIR6874.
- chr7:91,311,368–95,615,132, 80 genes, copy number 23–45 (broad region; genes not listed).
- chr10:34,109,560–38,080,877, 67 genes, copy number 14 (broad region; genes not listed).
- chr10:44,259,602–44,261,813, 1 gene, copy number 9: AL137026.2.
- chr10:45,854,093–46,330,207, 11 genes, copy number 10: PARGP1, RNA5SP310, RPL35AP23, TIMM23, SNORA74C-1, NCOA4, MSMB, RPL23AP61, AGAP7P, ANTXRLP1, ANTXRL.
- chr10:50,264,978–50,266,815, 1 gene, copy number 11: DYNC1I2P1.
- chr10:64,762,883–65,880,289, 8 genes, copy number 11–19: CYP2C61P, ANXA2P3, LINC02671, NEK4P3, MYL6P3, AL513321.1, AL592466.1, LINC01515.
- chr10:76,869,601–81,137,335, 96 genes, copy number 10 (broad region; genes not listed).
- chr10:111,787,233–126,421,879, 243 genes, copy number 12 (broad region; genes not listed).
- chr10:129,467,190–129,770,983, 4 genes, copy number 12 (within-gene range 4–12): MGMT, AL355531.1, AL157832.2, AL157832.1.
- chr12:12,310–5,046,788, 127 genes, copy number 11–20 (broad region; genes not listed).
- chr12:16,548,372–17,075,631, 8 genes, copy number 13 (within-gene range 4–13): LMO3, AC007552.2, AC007529.2, AC007529.1, SKP1P2, EEF1A1P16, AC092793.1, RNU6-837P.
- chr12:21,437,615–27,806,390, 119 genes, copy number 12 (broad region; genes not listed).
- chr12:28,133,249–29,784,759, 23 genes, copy number 12: CCDC91, AC022364.1, AC022364.2, AC022079.2, AC022079.1, RNU4-54P, RNA5SP355, AC084754.1, AC022081.1, AC024255.1, AC012150.1, FAR2, AC012150.2, AC009318.4, AC009318.1, AC009318.3, AC009318.2, ERGIC2, OVCH1-AS1, OVCH1, TMTC1, AC009320.1, RPL21P99.
- chr12:33,374,238–34,249,958, 18 genes, copy number 12–20: SYT10, AC023158.1, AC023158.2, AC016956.1, RNU6-400P, AC024153.1, RNU6-472P, Y_RNA, AC046130.1, ALG10, AC046130.2, AC140847.1, AC140847.3, TUBB8P4, AC140847.2, RNA5SP357, DUX4L27, AK6P1.
- chr14:18,333,726–19,677,923, 60 genes, copy number 9 (within-gene range 5–9): CR383658.1, RNU6-458P, CR383658.2, BNIP3P6, CR383656.10, CR383656.7, CR383656.13, CR383656.9, OR11H12, CR383656.6, ARHGAP42P5, LINC02297, CR383656.5, CR383656.1, CR383656.12, CR383656.8, CR383656.11, CR383656.3, RPL22P20, CR383656.4, CR383656.2, NF1P10, NEK2P1, NF1P7, MED15P1, AL929601.1, AL929601.2, POTEM, AL929601.3, RNU6-1239P, AL589182.1, GRAMD4P4, DUXAP9, AL589182.3, AL589743.3, NBEAP5, AL589182.2, OR11H13P, AL589743.2, AL589743.4, CDRT15P13, NBEAP6, AL589743.1, TOMM40P1, DUXAP10, BMS1P17, AL929602.1, LINC01297, GRAMD4P3, POTEG, AL512624.2, RNU6-1268P, MED15P6, NF1P4, AL512310.11, AL512624.1, NF1P11, AL512310.3, AL512310.10, AL512310.8.
- chr14:19,668,542–19,670,003, 2 genes, copy number 9 (within-gene range 5–9): AL512310.5, AL512310.6.
- chr17:59,893,046–59,950,574, 1 gene, copy number 16 (within-gene range 4–16): RPS6KB1.
- chr17:59,940,908–60,102,919, 14 genes, copy number 16: AC005702.1, RNFT1, TBC1D3P1-DHX40P1, RNFT1-DT, DHX40P1, TBC1D3P1, AC005702.4, AC005702.3, HEATR6, MIR4737, AC005702.2, AC025048.4, WFDC21P, AC025048.6.
- chr18:45,034–4,459,458, 100 genes, copy number 12 (broad region; genes not listed).
- chr18:5,232,876–6,463,015, 23 genes, copy number 11: AP001496.2, LINC00526, LINC00667, AP001496.3, ZBTB14, AP001496.1, AP005671.1, EPB41L3, AP005059.2, AP005059.1, MIR3976HG, MIR3976, TMEM200C, AP001021.1, AP001021.3, L3MBTL4, AP001021.2, RNU5F-3P, L3MBTL4-AS1, MIR4317, AP005060.1, RNU6-349P, RPL6P27.
- chr18:6,727,053–14,854,038, 216 genes, copy number 11–12 (broad region; genes not listed).
- chr18:20,946,906–21,183,499, 4 genes, copy number 10: ROCK1, AC022795.1, RNU6-120P, EXOGP1.
- chr19:23,525,631–28,313,500, 37 genes, copy number 10: ZNF675, AC073544.1, RPS27P29, VN1R93P, ZNF681, AC139769.1, BNIP3P39, AC139769.2, RPSAP58, AC139769.3, ZNF726, AC011503.1, AC011503.2, AC011503.3, RNA5-8SP4, AC092279.1, ZNF254, AC092279.2, BNIP3P40, AC073534.2, AC073534.1, ERVK-28, AC112702.1, LINC00662, AC006504.1, AC006504.5, AC006504.7, AC006504.3, SLC25A1P5, AC006504.2, AC006504.4, AC005357.2, AC006504.6, AC005758.1, AC005357.1, AC010511.1, AC020905.1.
- chr21:10,122,273–10,649,835, 13 genes, copy number 10: CR382287.1, CDRT15P8, AP003900.1, EIF3FP1, VN1R7P, AF254983.2, BAGE2, AF254983.1, TPTE, CYCSP41, SLC25A15P4, AF254982.1, IGHV1OR21-1.
- chr22:15,282,557–16,141,872, 34 genes, copy number 9: AP000542.3, AP000542.1, AP000542.2, ZNF72P, BNIP3P2, YME1L1P1, OR11H1, AP000534.2, ARHGAP42P3, AP000534.1, AP000533.2, AP000533.1, AP000533.3, AP000532.2, NEK2P2, AP000532.1, NF1P6, MED15P7, POTEH, POTEH-AS1, RNU6-816P, AP000529.1, PSLNR, GRAMD4P2, DUXAP8, AP000526.1, BMS1P22, AP000525.1, DUXAP8, NBEAP3, TOMM40P2, AP000522.1, AC145543.1, U6.

Autosomal genes at a single copy (total copy number 1): 722. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
